Somatic mutation profile of tumor specimen TCGA-60-2712-01A (aliquot TCGA-60-2712-01A-01D-1522-08) from TCGA case TCGA-60-2712, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.8 years (29,131 days).
Specimen TCGA-60-2712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65aff61-4684-4766-87a8-3c12ac65f553.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2712-11A (Solid Tissue Normal), aliquot TCGA-60-2712-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26b0e639-4260-4d0e-9fb0-eb18c85854c6

The open-access MAF lists 84 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 19, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 3, Intron 3, 5'UTR 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 35/103 reads (34%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ASB17 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52412050; called by muse, mutect2, varscan2
- ATG14 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs1165008099, COSV55958135; called by muse, mutect2, varscan2
- CADM2 | c.495G>T p.E165D (on ENST00000407528 / NM_001167674.2; = p.E167D on NM_153184.4) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV67403053; called by muse, mutect2, varscan2
- CAMSAP1 | c.4345G>T p.A1449S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV100409518, COSV56728343; called by muse, varscan2
- CCDC57 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58937180; called by muse, mutect2, varscan2
- CD1E | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs1396447226, COSV63772830; called by mutect2, varscan2
- CDC25B | c.881G>C p.S294T (on ENST00000245960 / NM_021873.3; = p.S280T on NM_004358.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV55659476; called by muse, mutect2, varscan2
- CHI3L1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs372451627; called by muse, mutect2, varscan2
- CLSTN2 | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 120/425 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71724966; called by muse, mutect2, varscan2
- COLEC12 | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101232132; called by muse, mutect2, varscan2
- CRX | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs142111462, COSV55759068; called by muse, mutect2, varscan2
- CRYGA | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs559628404, COSV58019145; called by muse, mutect2, varscan2
- DCTN1 | c.2182C>G p.Q728E | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV62621471; called by muse, mutect2, varscan2
- DMXL1 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV60720591; called by muse, mutect2, varscan2
- DNAH11 | c.5501G>A p.R1834H | Missense Mutation (SNP) | VAF 64/533 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs750430725, COSV60945433; ClinVar: uncertain significance; called by muse, varscan2
- DPP10 | c.200C>G p.T67S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59725645; called by muse, mutect2, varscan2
- DZANK1 | c.1744G>A p.E582K (on ENST00000262547 / NM_001099407.1; = p.E389K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52756953; called by muse, mutect2, varscan2
- EIF4B | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV50407761; called by muse, mutect2, varscan2
- EPAS1 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55390256; called by muse, mutect2, varscan2
- ERBB4 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53585637; called by muse, mutect2, varscan2
- FGD3 | c.1182+2T>C p.X394_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100490781; called by muse, mutect2, varscan2
- FOXP1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 52/151 reads (34%) | catalogued as COSV59554443; called by muse, mutect2, varscan2
- KIAA1109 | c.8470G>C p.E2824Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52691497; called by muse, mutect2, varscan2
- KIF18A | c.1949-1G>T p.X650_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV54187466; called by muse, mutect2
- KIF6 | c.817A>C p.I273L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54693893; called by muse, varscan2
- KRBA1 | c.537del p.T180Pfs*36 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV55445039; called by mutect2, pindel, varscan2
- MACF1 | c.11881G>A p.E3961K (on ENST00000372915; = p.E1894K on NM_012090.5) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV57143301; called by muse, mutect2, varscan2
- MAP2 | c.3725A>G p.Q1242R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200382253, COSV52307413; called by muse, mutect2, varscan2
- MYO3A | c.4001G>T p.R1334M | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV56347105, COSV56348641; called by muse, mutect2, varscan2
- NCAN | c.2327A>T p.D776V | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV53058496; called by muse, mutect2, varscan2
- NPSR1 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV62207450; called by muse, mutect2, varscan2
- OR13C2 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101604888; called by muse, mutect2, varscan2
- OR5K4 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 53/540 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61584310; called by muse, mutect2
- OR8B8 | c.833A>T p.Y278F | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60145699; called by muse, mutect2, varscan2
- PCDH15 | c.5073T>A p.S1691R | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV57390803; called by muse, mutect2, varscan2
- PCDHGA11 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as rs370020854; called by muse, mutect2, varscan2
- PCED1A | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV62314160; called by muse, mutect2, varscan2
- PGAP2 | c.409G>C p.E137Q (on ENST00000463452 / NM_001346398.2; = p.E198Q on NM_014489.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53467403; called by muse, mutect2, varscan2
- PIK3CG | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs927963993, COSV63253424; called by muse, mutect2, varscan2
- PITPNM2 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV54908589; called by muse, mutect2, varscan2
- PLEKHO1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV50311328; called by muse, mutect2, varscan2
- PRSS35 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs751533715, COSV63800555, COSV63801183; called by muse, mutect2, varscan2
- PUS7L | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61262959; called by muse, mutect2, varscan2
- RAPGEF1 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64702238; called by muse, mutect2, varscan2
- RIN3 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754628613, COSV53655182; called by muse, mutect2, varscan2
- SATB2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 85/316 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs765504446, COSV53492391, COSV99611217; called by muse, mutect2, varscan2
- SCLY | c.802-1G>A p.X268_splice (on ENST00000651534; = p.X260_splice on NM_016510.7) | Splice Site (SNP) | VAF 44/175 reads (25%) | catalogued as COSV54544313; called by muse, mutect2, varscan2
- SIRT2 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs200563255, COSV50877222; called by muse, mutect2, varscan2
- SLC38A2 | c.1233G>T p.W411C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.537); catalogued as rs779347880, COSV56746423; called by muse, mutect2, varscan2
- TTN | c.18325G>C p.V6109L (on ENST00000591111; = p.V5182L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | PolyPhen benign (0); catalogued as COSV59960199, COSV60337670; called by muse, varscan2
- USF3 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV57077246; called by muse, mutect2, varscan2
- VCPIP1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60047413, COSV60050141; called by muse, mutect2, varscan2
- ZCCHC2 | c.2096A>C p.E699A | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.174); catalogued as COSV54040976; called by muse, mutect2, varscan2
- ZNF443 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56894268; called by muse, mutect2, varscan2
- ZNF479 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs1554400213, COSV100482446, COSV58643443; called by muse, mutect2, varscan2
- PDE8B | c.770_786del p.G257Vfs*7 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel
- PTOV1 | c.422_423insA p.M142Hfs*58 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- SALL4 | c.798del p.Q266Hfs*24 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- SMCR8 | c.2284_2289del p.K762_P763del | In Frame Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- FCGBP | c.2913G>A p.V971= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs371925645; called by muse, mutect2, varscan2
- GALNT17 | c.651G>A p.V217= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100352451, COSV61190173; called by muse, mutect2, varscan2
- HOATZ | c.63G>T p.P21= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100239592; called by muse, mutect2, varscan2
- HUNK | c.369C>T p.I123= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV54231986; called by muse, mutect2, varscan2
- ITGAE | c.21G>T p.L7= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV53999652; called by muse, varscan2
- JPH2 | c.1872C>A p.P624= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100881787; called by muse, mutect2, varscan2
- KLF11 | c.1410G>T p.T470= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV59940560, COSV59941581; called by muse, mutect2, varscan2
- MAP4K4 | c.1905C>G p.S635= (on ENST00000347699 / NM_001242559.2; = p.S550= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56340358; called by muse, mutect2
- OR5R1 | c.795T>C p.N265= | Silent (SNP) | VAF 46/255 reads (18%) | catalogued as COSV56573632; called by muse, mutect2, varscan2
- PLB1 | c.1542C>T p.D514= | Silent (SNP) | VAF 58/254 reads (23%) | catalogued as COSV59835205; called by muse, mutect2, varscan2
- RARA | c.996C>T p.I332= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs780324094, COSV54196859; called by muse, mutect2, varscan2
- RYR1 | c.11107C>T p.L3703= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV62110309; called by muse, mutect2, varscan2
- SEMA3E | c.186G>C p.L62= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV57108165; called by muse, mutect2, varscan2
- SGK1 | c.9G>A p.V3= | Silent (SNP) | VAF 28/214 reads (13%) | catalogued as COSV52814898; called by muse, mutect2, varscan2
- SPATA31E1 | c.2745C>A p.T915= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV57790793, COSV57793525; called by muse, mutect2, varscan2
- SYNJ1 | c.4758G>T p.P1586= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV59156390, COSV99050419; called by muse, mutect2, varscan2
- TM4SF19 | c.423T>C p.G141= | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as COSV56557627; called by muse, varscan2
- TRPM1 | c.1827G>A p.Q609= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56642188; called by muse, varscan2
- ZNF99 | c.318T>C p.C106= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs766877148, COSV68056707; called by muse, mutect2, varscan2
- DEPDC5 | c.*659C>G | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as COSV56710367; called by muse, mutect2, varscan2
- MRPL22 | c.-2A>G | 5'UTR (SNP) | VAF 53/265 reads (20%) | catalogued as rs1044071127, COSV99501766; called by muse, mutect2, varscan2
- SPTB | c.6602+1301G>A | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV61552622; called by muse, varscan2
- USH1C | c.1284+7629G>T | Intron (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- USH1C | c.1284+7627dup | Intron (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
